Somatic mutation profile of tumor specimen TCGA-KL-8333-01A (aliquot TCGA-KL-8333-01A-11D-2310-10) from TCGA case TCGA-KL-8333, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 69.1 years (25,229 days).
Specimen TCGA-KL-8333-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88166f83-3da5-4f60-b5dd-8ffe235df44c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KL-8333-11A (Solid Tissue Normal), aliquot TCGA-KL-8333-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ecb0504-d83a-47d9-8496-1dd632f8d353

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAVIN3 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs1307841133; called by muse, mutect2, varscan2
- MAP7D1 | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs748839215, COSV60215119, COSV60217325; called by muse, mutect2, varscan2
- OR2M2 | c.349G>C p.V117L | Missense Mutation (SNP) | VAF 12/227 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV62899105, COSV62899474; called by muse, mutect2
- SH3PXD2A | c.2546G>A p.S849N (on ENST00000369774 / NM_001365079.1; = p.S821N on NM_014631.2) | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.197); catalogued as COSV100280413, COSV60118838; called by muse, mutect2
- UBA1 | c.1189A>G p.I397V | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs1556788826, COSV100256037; called by muse, mutect2, varscan2
- ADAMTS15 | c.1349_1368del p.L450Qfs*129 | Frame Shift Del (DEL) | VAF 14/86 reads (16%) | called by mutect2, pindel
- LETM1 | c.1646G>C p.S549T | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- ABCB11 | c.978T>G p.T326= | Silent (SNP) | VAF 9/142 reads (6%) | catalogued as COSV99792839; called by muse, mutect2
- FER1L6 | c.3162C>T p.N1054= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs770073727, COSV67547899; called by muse, mutect2, varscan2
- LETM1 | c.1647C>T p.S549= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs772990450; ClinVar: likely benign; called by muse, mutect2, varscan2
- RNF43 | c.318C>A p.I106= | Silent (SNP) | VAF 13/112 reads (12%) | called by muse, mutect2, varscan2
- DCAF4L1 | c.*3254A>T | 3'UTR (SNP) | VAF 12/156 reads (8%) | catalogued as COSV100048463; called by muse, mutect2
